Gene-level copy-number profile of tumor specimen TCGA-36-1575-01A from TCGA case TCGA-36-1575, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 83.8 years (30,592 days).
Specimen TCGA-36-1575-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.087e0085-480e-4f55-afa6-d48b2b42a960.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-36-1575-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0cd5ffda-7035-44dc-93af-5b31a7a3a6a4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 9; copy number 1: 3,503; copy number 2: 21,785; copy number 3: 29,379; copy number 4: 1,531; copy number 5: 926; copy number 6: 2,155; copy number 7: 131; copy number 8: 93; copy number 9: 216; copy number 10: 86.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-36-1575-01): tumor purity 0.97, ploidy 2.77, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 9 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:72,236,281–72,665,014, 1 gene (within-gene range 0–1): LINC01572.
- chr16:72,376,704–72,822,781, 6 genes: U6, AC004158.1, AC004943.2, RNU7-90P, KRT18P18, AC004943.3.
- chr16:72,805,998–72,821,992, 2 genes: AC004943.1, RNU7-71P.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 526 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:45,164,816–48,314,224, 62 genes, copy number 8 (within-gene range 6–8) (broad region; genes not listed).
- chr8:26,748,150–28,083,936, 36 genes, copy number 7 (within-gene range 1–7): ADRA1A, AC091675.1, COX6B1P4, AC067904.3, AC067904.1, MIR548H4, AC067904.2, AC090150.2, AC090150.1, STMN4, TRIM35, PTK2B, MIR6842, CHRNA2, EPHX2, GULOP, CLU, MIR6843, SCARA3, RNU6-1086P, AC013643.1, AC013643.3, MIR3622B, MIR3622A, AC013643.2, CCDC25, ESCO2, RNU6-1276P, PBK, AC104997.1, SCARA5, MIR4287, AC069113.1, AC069113.3, AC069113.2, NUGGC.
- chr8:28,348,287–29,064,764, 18 genes, copy number 9 (within-gene range 1–9): FBXO16, AC025871.3, AC025871.2, RNU6-178P, AC025871.1, FZD3, MIR4288, RNA5SP259, EXTL3, EXTL3-AS1, INTS9, INTS9-AS1, AC040975.1, HMBOX1, Metazoa_SRP, HMBOX1-IT1, RNA5SP260, AC108449.2.
- chr8:29,067,279–29,068,454, 1 gene, copy number 9: AC108449.3.
- chr8:30,331,961–31,033,715, 18 genes, copy number 9: AC109329.1, PPIAP84, TUBBP1, RBPMS-AS1, RBPMS, AC102945.2, GTF2E2, AC102945.1, SMIM18, RNU5A-3P, GSR, UBXN8, HIKESHIP3, PPP2CB, TEX15, AC090281.1, AC008066.1, PURG.
- chr16:34,266,041–35,912,516, 86 genes, copy number 9 (broad region; genes not listed).
- chr19:9,523,223–12,078,106, 147 genes, copy number 7–10 (within-gene range 3–10) (broad region; genes not listed).
- chr19:13,906,201–15,697,174, 93 genes, copy number 9 (within-gene range 5–9) (broad region; genes not listed).
- chr19:23,204,010–24,077,377, 34 genes, copy number 7 (within-gene range 3–7): AC092329.2, ZNF724, AC092329.3, BNIP3P38, IPO5P1, AC092329.1, AC092329.4, VN1R90P, VN1R91P, ZNF91, AC010300.1, BNIP3P8, CDC42EP3P1, LINC01224, VN1R92P, AC074140.1, ZNF725P, ZNF675, AC073544.1, RPS27P29, VN1R93P, ZNF681, AC139769.1, BNIP3P39, AC139769.2, RPSAP58, AC139769.3, AC011503.4, ZNF726, AC011503.1, AC011503.2, AC011503.3, RNA5-8SP4, AC092279.1.
- chr20:31,257,664–31,801,805, 31 genes, copy number 8 (within-gene range 3–8): DEFB115, DKKL1P1, AL121723.1, DEFB116, RPL31P3, HAUS6P2, RNA5SP480, DEFB117, DEFB118, AL031650.1, DEFB119, DEFB121, DEFB122, DEFB123, DEFB124, REM1, LINC00028, HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2.

Autosomal genes at a single copy (total copy number 1): 2,636. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
